Surgical pathology report (de-identified scan), TCGA case TCGA-FW-A3TU, project TCGA-SKCM (Skin Cutaneous Melanoma), tissue source site International Genomics Consortium, specimen TCGA-FW-A3TU-06A (Metastatic).

[page 1 of 3]
SURGICAL PATHOLOGY REPORT

Patient Name:

Med. Rec. #:

DOB/Gender:

Location:

Soc. Sec. #:

Physician(s):

Path No.:

Client:

Collected:

Received:

Reported:

Hosp #:

Pre-Operative/Clinical History

Right lung mass

Specimen(s) Received

A: RIGHT UPPER LOBE MASS

B: RIGHT HILAR NODES

C: RIGHT PULMONARY LIGAMENT

D: LOWER PARATRACHEAL NODE

Gross Description

Specimen A is received fresh from the operating room labeled right upper lobe mass and consists of a 10 gm, 6.8 x 3.0 x 2.3 cm wedge portion of lung.

Specimen type: Right upper lobe lung.

Procedure: Wedge resection.

Specimen integrity: Intact with a 7.8 cm suture line.

Laterality: Right.

Tumor site: Upper lobe.

Tumor size: 2.5 x 2.3 x 2.0 cm.

Tumor description: Well-circumscribed white mass with dark brown to black pigmented areas.

Tumor focality: Unifocal.

Pleural involvement: Abuts the pleura.

Vascular margins: Not applicable.

Staple margin of resection: 0.4 cm.

Bronchial margins: Not applicable.

Lung away from tumor: Spongy tan-pink (the mass encompasses approximately 90% of the wedge resection).

Lymph nodes:

Hilar:

No. examined: 0.

1CD-0-3

Melanoma, malignant, N0s

8720/3

Site: lung, upper lobe

C34.1

[page 2 of 3]
HISTOLOGY REPORT

Peribronchial:

No. examined: 0.

Other:

No. examined: 0.

Total examined: None examined.

Treatment effect: Not applicable.

A portion of the mass is submitted for frozen section analysis.

Representative sections are submitted as follows:

(A1FS) Frozen section
(A2, A3)) Mass and closest margins of resection
(A4-A6) Mass
(A7) Uninvolved lung.

Specimen B is received fresh from the operating room labeled right hilar lymph node and consists of a 1.9 x 1.0 x 0.6 cm aggregate of hemorrhagic yellow fatty tissue. A portion of the specimen is submitted for frozen section analysis.

The specimen is entirely submitted as follows:

(B1FS) Frozen section
(B2) Additional tissue.

Specimen C is received in formalin labeled right pulmonary ligament node and consists of a 1.5 x 0.7 x 0.5 cm yellow fatty tissue fragment. The cut surfaces show a central tan-gray 1.1 cm in maximum diameter lymph node. The specimen is bisected and entirely submitted in cassette (C1).

Specimen D is received in formalin labeled 4R lower paratracheal, the requisition denotes lower paratracheal node, and consists of four irregular gray-black anthracotic nodules varying from 0.6 to 1.5 cm in maximum diameter. The cut surface of the larger lymph node shows well-circumscribed solid white 0.1 cm areas.

The larger nodes are inked and sectioned, the smaller submitted in toto as follows:

(D1) Two potential whole nodes and a bisected node
(D2 Largest node, bisected.

Intraoperative Consultation

(AF1) Frozen section diagnosis: "malignant tumor" is rendered by Dr.

(BF1) Frozen section diagnosis: "lymph node, no tumor seen" is rendered by Dr.

Microscopic Description

Specimen A sections demonstrate lung with a large nodule of metastatic malignant melanoma.

The tumor cells (A6) demonstrate the following immunostain results:

S100	Positive
HMB-45	Positive
Mart-1	Positive

The parenchymal resection margin is not involved by melanoma.

Sections (BF1, B2, C1, D1) demonstrate benign lymph node tissue. There is anthracotic pigment deposition. No metastatic malignancy is seen.

Sections (D2) demonstrate lymph node with metastatic malignant melanoma.

[page 3 of 3]
HISTOLOGY REPORT

Diagnosis

SPECIMEN A, LUNG, RIGHT UPPER LOBE, WEDGE BIOPSY:
METASTATIC MALIGNANT MELANOMA.
PARENCHYMAL RESECTION MARGINS NOT INVOLVED.

SPECIMEN B, RIGHT HILAR LYMPH NODE, EXCISIONAL BIOPSY:
THREE LYMPH NODES IDENTIFIED.
NO METASTATIC TUMOR SEEN.
ANTHRACOSIS.

SPECIMEN C, RIGHT PULMONARY LIGAMENT LYMPH NODE, EXCISIONAL BIOPSY:
ONE LYMPH NODE IDENTIFIED.
NO METASTATIC TUMOR SEEN.
ANTHRACOSIS.

SPECIMEN D, 4R LOWER PARATRACHEAL LYMPH NODES, EXCISIONAL BIOPSY:
FOUR LYMPH NODES IDENTIFIED.
METASTATIC MALIGNANT MELANOMA IN ONE LYMPH NODE.

***Electronically Reviewed and Signed Out By

Comment

Positive and negative controls react satisfactorily.

FDA required disclaimer: These tests were developed and their performance characteristics determined by or approved by the U.S. Food and Drug Administration. The FDA has determined that such clearance or approval is not necessary. These tests are used for clinical purposes and should not be regarded as investigational or for research. This laboratory is certified under the Clinical Improvement Amendments of 1988 (CLIA) as qualified to perform high complexity clinical laboratory testing. They have not been cleared

College of American Pathologists (CAP) - required information for predictive/prognostic markers: 1. Type of specimen fixation and detection system: Tissue is fixed in 10% formalin. Indirect biotin-free detection kit is used. 2. Clones used: ER (clone 6F11) ; PR (clone PGR 636)
CD117 (polyclonal, approved); KI-67 (clone K3, p53 (clone DO7,
MSH6 (clone BC-44, Bluecare), MSH2 3 clone G214-1129), MLH1 (Cell Marque clone G168-72a), RMR2 (clone MRQ-28, Cell
3. Criteria for positive results: ER and PR: $\geq 1\%$ of tumor cells with nuclear staining; HER2: $>30\%$ of cells show complete membrane staining; p53: $\geq 10\%$ of tumor cells with nuclear staining; MMR Proteins: complete absence of tumor nuclear staining.

CPT Code(s)

Source: NCI Genomic Data Commons file b4ad5756-c2d0-4f52-8a5f-a21932af59bf (TCGA-FW-A3TU.8C43518B-770C-48B6-A58D-B6A9AC9232FC.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).